Somatic mutation profile of tumor specimen 0DQQBW from CCDI case PBCFHV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 15.4 years (5,612 days).
Specimen 0DQQBW: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04ad83a0-22b0-496e-a9e5-dac1bcd4182b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQQCT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/086a4a3f-f183-44e1-9b45-abc9f316ddd7

The open-access MAF lists 28 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Intron 5, Silent 5, Frame Shift Del 2, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 576/882 reads (65%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EFHC2 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 123/159 reads (77%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1027804231; called by muse, mutect2, varscan2
- GLI2 | c.1947C>G p.S649R (on ENST00000361492 / NM_001374353.1; = p.S666R on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 107/799 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV58050739; called by muse, mutect2, varscan2
- HNRNPM | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 29/309 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.137); catalogued as COSV57694189; called by muse, mutect2
- ANKRD16 | c.213del p.Y71* | Frame Shift Del (DEL) | VAF 31/248 reads (13%) | called by mutect2, pindel, varscan2
- ANKRD40CL | c.251_253del p.K84del (on ENST00000643007; = p.K56del on NM_001358683.3) | In Frame Del (DEL) | VAF 182/381 reads (48%) | called by pindel, varscan2
- CNTNAP2 | c.171C>G p.S57R | Missense Mutation (SNP) | VAF 75/824 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.377); called by muse, mutect2
- CSTF2T | c.1672C>T p.Q558* | Nonsense Mutation (SNP) | VAF 108/736 reads (15%) | called by muse, mutect2, varscan2
- DHX33 | c.2080G>T p.A694S | Missense Mutation (SNP) | VAF 63/367 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- EHMT1 | c.3721G>C p.D1241H | Missense Mutation (SNP) | VAF 101/439 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF2C | c.507G>A p.M169I | Missense Mutation (SNP) | VAF 239/738 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- MYO1C | c.496_502del p.R166Vfs*101 (on ENST00000648651 / NM_001080779.2; = p.R131Vfs*101 on NM_033375.5) | Frame Shift Del (DEL) | VAF 189/368 reads (51%) | called by mutect2, pindel, varscan2
- OR2L8 | c.390C>A p.H130Q | Missense Mutation (SNP) | VAF 402/1070 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.045); called by mutect2, varscan2
- PATJ | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 148/328 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- PTPRZ1 | c.6289C>A p.H2097N | Missense Mutation (SNP) | VAF 224/1084 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- RAET1L | c.624T>G p.S208R | Missense Mutation (SNP) | VAF 184/579 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- SPTA1 | c.2575A>G p.M859V | Missense Mutation (SNP) | VAF 142/602 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- TIAM1 | c.4403A>C p.E1468A | Missense Mutation (SNP) | VAF 171/676 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ADGRB1 | c.609G>A p.S203= | Silent (SNP) | VAF 166/562 reads (30%) | called by muse, mutect2, varscan2
- DNM1L | c.528T>C p.N176= | Silent (SNP) | VAF 167/548 reads (30%) | called by muse, mutect2, varscan2
- POSTN | c.855T>G p.G285= | Silent (SNP) | VAF 147/825 reads (18%) | called by muse, mutect2, varscan2
- RYR1 | c.3027G>A p.V1009= | Silent (SNP) | VAF 100/331 reads (30%) | called by muse, mutect2, varscan2
- STAM | c.813A>G p.E271= | Silent (SNP) | VAF 36/308 reads (12%) | called by muse, mutect2, varscan2
- CZIB | c.7-66G>A | Intron (SNP) | VAF 56/107 reads (52%) | called by muse, mutect2, varscan2
- MCM9 | c.1030+63T>C | Intron (SNP) | VAF 28/142 reads (20%) | called by muse, mutect2, varscan2
- PAK1 | c.597+13G>A | Intron (SNP) | VAF 112/161 reads (70%) | catalogued as rs769776073; called by muse, mutect2, varscan2
- PDE4A | c.320+9938C>T | Intron (SNP) | VAF 109/693 reads (16%) | catalogued as rs753643157; called by muse, mutect2, varscan2
- SAMSN1 | c.235+71C>T | Intron (SNP) | VAF 64/272 reads (24%) | called by muse, mutect2, varscan2
